Somatic mutation profile of tumor specimen MP2PRT-PATJUZ-TBP1-A (aliquot MP2PRT-PATJUZ-TBP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATJUZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,639 days).
Specimen MP2PRT-PATJUZ-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c1f5fc6-3000-489f-a2bf-1790fabcc653.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATJUZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATJUZ-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4cff50b7-d699-4835-85d3-08774bdde7d2

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KATNB1 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 14/365 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.273); catalogued as rs782335200; called by muse, mutect2
- PPFIA2 | c.869G>C p.R290P | Missense Mutation (SNP) | VAF 32/530 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100332399, COSV61054172; called by muse, mutect2
- DLGAP4 | c.2486C>T p.T829I (on ENST00000339266 / NM_001365621.1; = p.T826I on NM_014902.6) | Missense Mutation (SNP) | VAF 21/382 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.425); called by muse, mutect2
- CCDC85A | c.600C>T p.T200= | Silent (SNP) | VAF 71/832 reads (9%) | catalogued as rs776970983; called by muse, mutect2
